Gene-level copy-number profile of tumor specimen TCGA-58-8391-01A from TCGA case TCGA-58-8391, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 57.8 years (21,102 days).
Specimen TCGA-58-8391-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.4735222e-a2ca-4771-8321-252955940ddd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-58-8391-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e930885e-062a-47c6-8c2e-55fc531aec16

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 1,923; copy number 2: 15,287; copy number 3: 22,582; copy number 4: 13,711; copy number 5: 2,558; copy number 6: 1,821; copy number 7: 131; copy number 8: 1,368; copy number 9: 233; copy number 11: 74; copy number 12: 43; copy number 20: 14; copy number 34: 6; copy number 42: 20; copy number 52: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-58-8391-01A-11D-2322-01): tumor purity 0.62, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–23,672,387, 25 genes (within-gene range 0–2): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,902 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:132,671,788–133,568,463, 1 gene, copy number 8 (within-gene range 6–8): NCKAP5.
- chr2:133,117,004–142,131,016, 81 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr2:142,131,178–186,422,432, 596 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr3:161,600,438–161,821,908, 2 genes, copy number 8 (within-gene range 6–8): AC112770.1, AC131211.1.
- chr3:175,609,479–198,222,513, 491 genes, copy number 8–9 (broad region; genes not listed).
- chr5:50,396,192–51,665,048, 21 genes, copy number 8: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2.
- chr5:72,087,782–72,771,733, 13 genes, copy number 11 (within-gene range 2–11): AC025774.1, MAP1B, MIR4803, MRPS27, RN7SL153P, PTCD2, AC093278.1, YBX1P5, AC093278.2, ZNF366, LINC02056, AC063979.1, RPL7P22.
- chr6:45,328,157–46,491,972, 11 genes, copy number 8–12 (within-gene range 6–12): RUNX2, AL096865.1, RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1.
- chr7:87,934,143–90,391,453, 30 genes, copy number 7 (within-gene range 4–7): ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1, RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3.
- chr7:98,106,862–108,456,717, 297 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr11:56,741,223–57,335,892, 22 genes, copy number 8 (within-gene range 3–8): OR9G4, MIR6128, AP001803.10, OR9G2P, OR5G1P, OR5G4P, OR5G5P, OR5G3, LINC02735, FADS2B, OR5AK3P, OR5AK2, OR5AK1P, OR5BQ1P, OR5AK4P, OR5AO1P, OR5BP1P, LRRC55, APLNR, TNKS1BP1, AP000781.1, SSRP1.
- chr11:69,294,151–69,367,726, 1 gene, copy number 8 (within-gene range 3–8): MYEOV.
- chr11:69,371,463–72,674,591, 118 genes, copy number 8 (broad region; genes not listed).
- chr11:72,685,075–72,708,565, 4 genes, copy number 8: ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20.
- chr12:7,108,052–7,158,945, 6 genes, copy number 8: C1RL-AS1, RBP5, RNU6-485P, AC018653.3, CLSTN3, AC018653.4.
- chr17:39,027,277–41,190,639, 119 genes, copy number 7–52 (broad region; genes not listed).
- chr18:26,226,445–27,247,188, 21 genes, copy number 7: TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908.
- chr18:27,343,252–27,420,435, 4 genes, copy number 7: AC021382.1, UBA52P9, AC068408.1, RBM22P1.
- chr21:23,704,260–28,674,848, 64 genes, copy number 7–20 (within-gene range 2–20) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,923. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
